Surgical pathology report (de-identified scan), TCGA case TCGA-XF-A9T4, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-A9T4-01A (Primary Tumor).

[page 1 of 6]
Collected
Quoted by

Location

DIAGNOSIS:

RADICAL CYSTOPROSTATECTOMY WITH PELVIC LYMPH NODE DISSECTION AND ORTHOTOPIC URINARY DIVERSION TO URETHRA:

RIGHT DISTAL URETER (AFS):

FROZEN SECTION DIAGNOSIS:

- NO HIGH GRADE ATYPIA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT DISTAL URETER (BFS):

FROZEN SECTION DIAGNOSIS:

- NO HIGH GRADE ATYPIA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

RIGHT COMMON ILIAC LYMPH NODES (C):

- NO MALIGNANCY IDENTIFIED IN FOUR LYMPH NODES EXAMINED (0/4)

PRE SACRAL LYMPH NODES (D):

- NO MALIGNANCY IDENTIFIED IN SEVEN LYMPH NODES EXAMINED (0/7)

RIGHT EXTERNAL ILIAC LYMPH NODES (E):

- NO MALIGNANCY IDENTIFIED IN EIGHT LYMPH NODES EXAMINED (0/8)

RIGHT LYMPH NODE OF CLOQUET (F):

- NO MALIGNANCY IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

RIGHT OBTURATOR/HYPOGASTRIC LYMPH NODES (G):

- METASTATIC CARCINOMA IDENTIFIED IN ONE OF SEVEN LYMPH NODES EXAMINED (1/7)

RIGHT PARA CAVAL LYMPH NODES (H):

- NO MALIGNANCY IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

APICAL URETHRAL MARGIN (IFS):

INTRAOPERATIVE FROZEN SECTION DIAGNOSIS:

- NO HIGH GRADE ATYPIA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN PROSTATIC URETHRAL TISSUE

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

BLADDER/PROSTATE (J):

BLADDER:

- EXOPHYTIC INVASIVE POORLY DIFFERENTIATED UROTHELIAL CARCINOMA (3.3 X 2.5 X 2 CM), GRADE 3-4/4, LARGELY REPLACING RIGHT URETEROVESICAL JUNCTION (WITHOUT OBSTRUCTION), EXTENDING INTO DEEP MUSCULARIS PROPRIA AND APPROACHING BUT NOT INVOLVING PERIVESICAL SOFT TISSUE
- NO LYMPHOVASCULAR INVASION SEEN
- NO UROTHELIAL CARCINOMA IN SITU (FLAT LESION) IDENTIFIED
- RANDOM BLADDER MUCOSA INCLUDING TRIGONE AND BLADDER NECK, NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED
- RESECTION MARGINS, FREE OF UROTHELIAL DYSPLASIA AND MALIGNANCY

PROSTATE:

- FOCAL HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN II-III)
- NO PROSTATIC ADENOCARCINOMA IDENTIFIED

ICD O-3
Carcinoma, urothelial NOS
812013
Site Bladder NOS
C67.9
7/28/26/14

[page 2 of 6]
Directed by
Ordered by

Location

- PROSTATIC URETHRA, NO UROTHELIAL DYSPLASIA OR UROTHELIAL MALIGNANCY IDENTIFIED
- BILATERAL SEMINAL VESICLES, NO SIGNIFICANT HISTOPATHOLOGIC CHANGE

LEFT PARA AORTIC LYMPH NODES (K):

- NO MALIGNANCY IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

LEFT COMMON ILIAC LYMPH NODES (L):

- NO MALIGNANCY IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

LEFT EXTERNAL ILIAC LYMPH NODES (M):

- NO MALIGNANCY IDENTIFIED IN FIVE LYMPH NODES EXAMINED (0/5)

LEFT LYMPH NODE OF CLOQUET (N):

- NO MALIGNANCY IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

LEFT OBTURATOR/HYPOGASTRIC LYMPH NODES (O):

- NO MALIGNANCY IDENTIFIED IN 12 LYMPH NODES EXAMINED (0/12)

LEFT PRESACRAL LYMPH NODES (P):

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE EXAMINED (0/1) [ENTIRELY SUBMITTED]

RIGHT PRESACRAL LYMPH NODES (Q):

- NO MALIGNANCY IDENTIFIED IN FOUR LYMPH NODES EXAMINED (0/4)

RIGHT PROXIMAL URETER (R):

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT PROXIMAL URETER (S):

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LYMPH NODE SUMMARY: METASTATIC CARCINOMA IDENTIFIED IN ONE OF 61 LYMPH
NODES EXAMINED (1/61)

PATHOLOGIC TNM STAGE: pT2bN1MX

COMMENT:

Representative sections of invasive carcinoma are submitted for p53 assay by immunohistology, results of which will be issued in an addendum.

SPECIMEN SOURCE:

AFS: "Rt distal ureter"
BFS: "Left distal ureter F/S"
C: "Rt common iliac LN"
D: "Pre sacral LN"
E: "Rt external iliac LN"
F: "Rt LN of cloquet"
G: "Rt obturator/hypogastric LN"
H: "Rt para caval LN"
IFS: "Apical urethral margin-f/s"
J: "Bladder/prostate"

[page 3 of 6]
SURGICAL PATHOLOGY REPORT

Collected

Ordered by

Location

K: "Left para aortic LN"
L: "Lt. common iliac LN"
M: "Lt. external iliac LN"
N: "Lt. LN of Cloquet"
O: "Lt. obturator/hypogastric LN"
P: "Lt. presciatic LN"
Q: "Rt. presciatic LN"
R: "Rt. proximal ureter"
S: "Lt. proximal ureter"

CLINICAL INFORMATION:

Pre-Op Dx: Bladder cancer

Post-Op Dx: Same as pre-op

GROSS EXAMINATION:

A: The specimen is received fresh from the O.R. and labeled "Rt distal ureter". It consists of a segment of ureter that measures 0.3 cm in length by 0.3 cm in diameter. Entirely submitted for frozen section in cassette AFS.

B: The specimen is received fresh from the O.R. and labeled "Left distal ureter F/S". It consists of a segment of ureter that measures 0.4 cm in length by 0.3 cm in diameter. Entirely submitted for frozen section in cassette BFS.

C: The specimen is received in formalin and labeled "Rt common iliac LN". It consists of a single tan-yellow piece of fatty tissue measuring 2.5 x 2 x 0.6 cm. Entirely submitted in one cassette.

D: The specimen is received in formalin and labeled "Pre sacral LN". It consists of a single tan-yellow to purple piece of fatty tissue measuring 4.5 x 2 x 1 cm. Multiple lymph nodes are identified ranging from 0.3 to 0.7 cm in greatest dimension. Entirely submitted in three cassettes.

E: The specimen is received in formalin and labeled "Rt external iliac LN". It consists of multiple tan-yellow pieces of fatty tissue measuring 5 x 3.5 x 1.5 cm in aggregate. Multiple lymph nodes are identified, the largest measuring 2.2 cm in greatest dimension. Entirely submitted in four cassettes.

F: The specimen is received in formalin and labeled "Rt LN of cloquet". It consists of a single tan-yellow piece of fatty tissue measuring 2.5 x 1.5 x 1 cm. A single lymph node is identified measuring 1.2 cm in greatest dimension. Entirely submitted in one cassette.

G: The specimen is received in formalin and labeled "Rt obturator/hypogastric LN". It consists of multiple pieces of tan-yellow fatty tissue measuring 4.5 x 4 x 1 cm in aggregate. Multiple lymph nodes are identified, the largest node measures 1.3 x 1 x 0.6 cm. Entirely submitted in three cassettes.

H: The specimen is received in formalin and labeled "Rt para caval LN". It consists of a single tan-yellow piece of fatty tissue measuring 3 x 1.5 x 1.5 cm. One lymph node measuring 0.5 cm in greatest dimension is identified. Entirely submitted in two cassettes.

I: The specimen is received fresh from the O.R. and labeled "Apical urethral margin-f/s". It consists of a single piece of tan-pink tissue measuring 2 x 0.4 x 0.3 cm. Entirely submitted for frozen section in cassette IFS.

J: The specimen is received fresh from the O.R. and labeled "Bladder/prostate". It consists of a radical cystoprostatectomy specimen measuring overall 22 x 13.5 x 2.5 cm. The attached peritoneum measures 16 x 13 x 0.1 cm and is yellow-tan,

[page 4 of 6]
Collected
Ordered by

Location

glistening and freely mobile. The non-peritonealized surface is inked black with red ink superimposed along the right side of the prostate. The specimen is opened anteriorly along the prostatic urethra and anterior bladder wall. The bladder measures 5 x 6 x 3 cm with a wall thickness of 1.3 cm. The right attached ureter measures 4.5 cm in length and 1.1 cm in circumference with a normal pink-tan mucosa. The left attached ureter measures 5.3 cm in length and 0.6 cm in circumference with a tan-pink normal appearing mucosa. Located at the right ureterovesical junction is a tan-pink, raised, soft, polypoid mass measuring 3.3 x 2.5 x 2 cm. It completely encircles without obstructing the ureterovesical junction on the right side. Sectioning through the mass shows full wall thickness involvement with possible extension into perivesical fat. The wall in the involved area measures 2 cm in thickness. The remaining bladder mucosa appears tan-pink and is unremarkable. No other lesions are identified. The prostate measures 3 x 4.5 x 3.5 cm. The prostatic urethra measures 2.5 cm in length and 1.6 cm in circumference and is not excavated. The verumontanum measures 0.7 x 0.5 x 0.4 cm. The prostate is serially sectioned. The cut surfaces appear tan and unremarkable. The left seminal vesicle measures 3 x 1.5 x 0.8 cm, and the right seminal vesicle measures 3 x 1.8 x 0.8 cm. Both appear normal. Representative sections are submitted in 30 cassettes.

K: The specimen is received in formalin and labeled "Left para aortic LN". It consists of a single tan-yellow piece of fatty tissue measuring 2 x 1.5 x 1 cm. One lymph node measuring 1 cm in greatest dimension is identified. Entirely submitted in one cassette.

L: The specimen is received in formalin and labeled "Lt. common iliac LN". It consists of multiple pieces of tan-yellow fatty tissue measuring 2.5 x 2 x 1 cm in aggregate. Multiple lymph nodes ranging from 0.3 cm to 0.5 cm in greatest dimension are identified. Entirely submitted in one cassette.

M: The specimen is received in formalin and labeled "Lt. external iliac LN". It consists of multiple pieces of tan-yellow fatty tissue measuring 4 x 2.5 x 1 cm in aggregate. Multiple lymph nodes are identified, the largest measuring 1.2 cm in greatest dimension. Entirely submitted in two cassettes.

N: The specimen is received in formalin and labeled "Lt. LN of Cloquet". It consists of a single tan-yellow piece of fatty tissue measuring 1.5 x 1 x 1 cm. One lymph node measuring 1 cm in greatest dimension is identified. Entirely submitted in one cassette.

O: The specimen is received in formalin and labeled "Lt. obturator/hypogastric LN". It consists of multiple pieces of tan-yellow fatty tissue measuring 4 x 3.5 x 1.5 cm in aggregate. Multiple lymph nodes ranging from 0.3 to 1.5 cm in greatest dimension are identified. Entirely submitted in three cassettes.

P: The specimen is received in formalin and labeled "Lt. presciatic LN". It consists of multiple pieces of tan-yellow fatty tissue measuring 3 x 2 x 0.6 cm in aggregate. Entirely submitted in one cassette.

Q: The specimen is received in formalin and labeled "Rt. presciatic LN". It consists of multiple pieces of tan-yellow fatty tissue measuring 2 x 1.5 x 0.5 cm in aggregate. Multiple small lymph nodes ranging from 0.3 to 0.4 cm in greatest dimension are identified. Entirely submitted in one cassette.

R: The specimen is received in formalin and labeled "Rt. proximal ureter". It consists of a segment of ureter measuring 1 cm in length and 0.3 cm in diameter. The proximal end is submitted in one cassette.

S: The specimen is received in formalin and labeled "Lt. proximal ureter". It consists of a segment of ureter measuring 0.9 cm in length and 0.3 cm in diameter.

[page 5 of 6]
Collected:
Ordered by:

Location:

The proximal end is submitted in one cassette.

SECTIONS:

AFS: frozen section, right distal ureter
BFS: frozen section, left distal ureter
C: right common iliac lymph nodes - all embedded
D1-3: presacral lymph nodes - all embedded
E1-4: right external iliac lymph nodes - all embedded
F: right lymph node of Cloquet - all embedded
G1: right obturator/hypogastric lymph nodes; largest lymph node, bisected
G2,3: remaining tissue
H1,2: right paracaval lymph nodes - all embedded
IFS: frozen section, apical urethral margin
J1-10: bladder/prostate; bladder tumor at right ureterovesical junction
J11: tumor edge and adjacent mucosa
J12: anterior bladder wall
J13: right lateral bladder wall
J14: dome of bladder
J15: left lateral bladder wall
J16: left ureterovesical junction
J17: posterior bladder wall
J18: trigone and bladder neck
J19: right perivesical fat for possible lymph nodes
J20: left perivesical fat for possible lymph nodes
J21: right distal prostate
J22: left distal prostate
J23: right mid prostate
J24: left mid prostate
J25,26: right anterior, posterior proximal prostate
J27,28: left anterior, posterior proximal prostate
J29,30: right and left seminal vesicles and prostatic junction
K: left para-aortic lymph nodes - all embedded
L: left common iliac lymph nodes - all embedded
M1,2: left external iliac lymph nodes - all embedded
N: left lymph node of Cloquet - all embedded
O1-3: left obturator/hypogastric lymph nodes - all embedded
P: left presciatic lymph nodes - all embedded
Q: right presciatic lymph nodes - all embedded
R: right proximal ureter
S: left proximal ureter

INTRAOPERATIVE FROZEN CONSULTATION:

AFS: Right distal ureter:
- no high grade atypia or tumor identified

BFS: Left distal ureter:
- no high grade atypia or tumor identified

IFS: Apical urethral margin:
- no high grade atypia or tumor identified

MICROSCOPIC EXAMINATION:

A-I: See final microscopic-diagnosis.

[page 6 of 6]
Collected:

Ordered by:

Location:

J: Sections of the bladder show a deeply invasive poorly differentiated urothelial carcinoma (J1-11). The tumor extends almost but not completely through the muscularis propria of the bladder wall (J3) where it approaches without involving the perivesical soft tissue. No associated in situ carcinoma (flat lesion) is seen around the invasive tumor or in additional random sections of the bladder. All resection margins are free of both urothelial dysplasia and invasive carcinoma.

K-8: See final microscopic-diagnosis.

*Rev discrepancy note in open Clinica,
TCGA tumor contains 10% squamous.*

Source: NCI Genomic Data Commons file aa40b04c-13f6-495e-9050-81e8590ba85a (TCGA-XF-A9T4.82129FB4-5062-4878-931D-C09C336EAE4A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).